Surgical pathology report (de-identified scan), TCGA case TCGA-EJ-A7NK, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site University of Pittsburgh, specimen TCGA-EJ-A7NK-01A (Primary Tumor).

Collection Date:

FINAL DIAGNOSIS:

**PART 1: LYMPH NODES, RIGHT PELVIC, EXCISION –
NO EVIDENCE OF NEOPLASIA IN TWENTY (20) LYMPH NODES EXAMINED.**

**PART 2: LYMPH NODES, LEFT PELVIC, EXCISION –
NO EVIDENCE OF NEOPLASIA IN TWENTY EIGHT (28) LYMPH NODES EXAMINED.**

PART 3: PROSTATE AND BILATERAL SEMINAL VESICLES, RADICAL PROSTATECTOMY –

- A. INVASIVE POORLY DIFFERENTIATED ADENOCARCINOMA, GLEASON SCORE 3 + 4 = 7.**
- B. THE CARCINOMA INVOLVES BOTH THE RIGHT AND LEFT LOBES AND HAS A GREATEST NODULAR DIAMETER OF 1.4 CM.**
- C. THE CARCINOMA INVOLVES APPROXIMATELY 10% OF THE EXAMINED PROSTATE VOLUME.**
- D. THE CARCINOMA SHOWS FOCAL EXTRACAPSULAR EXTENSION.**
- E. THE EXTRACAPSULAR EXTENSION IS SEEN IN THE POSTERIOR LEFT BASE REGION (SLIDE 3Z).**
- F. BILATERAL SEMINAL VESICLES ARE FREE OF CARCINOMA.**
- G. ALL EXAMINED SURGICAL RESECTION MARGINS ARE FREE OF CARCINOMA.**
- H. PERINEURAL INVASION IS IDENTIFIED.**
- I. NO ANGIOLYMPHATIC INVASION IS IDENTIFIED.**
- J. HIGH-GRADE PROSTATIC INTRAEPITHELIAL NEOPLASIA IS IDENTIFIED.**
- K. PATHOLOGIC TNM STAGE: PT3a N0 MX.**
- L. TNM HISTOLOGIC GRADE = G3.**
- M. BENIGN PROSTATIC HYPERTROPHY AND CHRONIC MODERATELY ACTIVE PROSTATITIS ARE NOTED.**

PART 4:
SOFT TISSUE, LEFT PEDICLE, BIOPSY.
A. FRAGMENTS OF BENIGN FIBROADIPOSE TISSUE AND NEURAL TISSUE.
B. NEGATIVE FOR PROSTATIC TISSUE OR MALIGNANCY.

ICD-6-3

Adenocarcinoma, acinar 8/40/3

Adenocarcinoma NOS 8140/3

Site Prostate NOS C61.9

9/24/13

CASE SYNOPSIS:

SYNOPTIC DATA - PRIMARY PROSTATE TUMORS

CLINICAL DATA:	PSA value: 8.5	Aden
INVASIVE CA IDENTIFIED?:	Yes	
TUMOR HISTOLOGY:	Adenocarcinoma NOS	Si
PRIMARY GLEASON GRADE:	3	
SECONDARY GLEASON GRADE:	4	
GLEASON SUM SCORE:	7	
GLEASON 4/5 PERCENTAGE:	20%	
WEIGHT OF PROSTATE:	37.42gm	
TUMOR SIZE:	Maximum dimension: 1.4 cm	
LOBE LATERALITY:	Right and Left Lobes	
PERCENT OF SPECIMEN INVOLVED BY TUMOR:	5 - 25%	
MULTIFOCAL DISEASE:	Yes	
HIGH GRADE PIN:	Yes - NOS	
EXTRAPROSTATIC EXTENSION:	Yes - Focal	
PERINEURAL INVASION:	Yes	
ANGIOLYMPHATIC INVASION:	No	
SEMINAL VESICLE INVASION:	No	
SURGICAL MARGIN INVOLVEMENT:	All surgical margins free of tumor	
LYMPH NODES EXAMINED:	48	
LYMPH NODES POSITIVE:	0	
T STAGE, PATHOLOGIC:	pT3a	
N STAGE, PATHOLOGIC:	pN0	
M STAGE, PATHOLOGIC:	pM0	
HISTOLOGIC GRADE:	G3-4, Poorly differentiated/undifferentiated	

Source: NCI Genomic Data Commons file 54599f50-1d46-4738-b724-5b26510bc4ef (TCGA-EJ-A7NK.E1362D2A-6ED3-4BA3-A92D-63C5024946A6.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).